MMRF case MMRF_2310 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e9b45c72-c531-42f1-9bd6-97e70020540c

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.7 years (24,726 days); ISS stage: II; Days to last known disease status: 822 days (2.3 years); Days to last follow up: 822 days (2.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 8 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 43 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 95 days; Days to treatment end: 95 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 119 days; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Dexamethasone + Elotuzumab; Regimen or line of therapy: Second line of therapy; Days to treatment start: 605 days (1.7 years); Days to treatment end: 648 days (1.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 605 days (1.7 years); Days to treatment end: 655 days (1.8 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Third line of therapy; Days to treatment start: 666 days (1.8 years); Days to treatment end: 759 days (2.1 years).
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 666 days (1.8 years); Days to treatment end: 815 days (2.2 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Third line of therapy; Days to treatment start: 815 days (2.2 years); Days to treatment end: 815 days (2.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 0): M Protein 3.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 56.9 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 4.37 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 69 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 9.8 g/dL; Glucose 15.3 mmol/L.
- Day 78 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.812 mg/dL; Immunoglobulin G 6.88 g/L; Immunoglobulin A 0.6 g/L; Immunoglobulin M 0.86 g/L; Beta 2 Microglobulin 1.3 µg/mL; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 19.4 mmol/L.
- Day 192 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.879 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.872 mg/dL; Immunoglobulin G 7.97 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 4.29 mmol/L.
- Day 290 (ECOG 1): M Protein 0.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.79 g/L; Beta 2 Microglobulin 1.23 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 126 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 48 g/L; Total Protein 7.4 g/dL; Glucose 22.5 mmol/L.
- Day 394 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 1.17 g/L; Beta 2 Microglobulin 1.24 µg/mL; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 9.52 mmol/L.
- Day 455 (ECOG 1): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.86 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 12.4 mmol/L.
- Day 520 (ECOG 1): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.63 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 15.6 mmol/L.
- Day 641 (ECOG 1): M Protein 2.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.756 mg/dL; Immunoglobulin G 30.2 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 4.67 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 96 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 8.2 g/dL; Glucose 7.59 mmol/L.
- Day 722 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.923 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 4.72 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 11.8 mmol/L.
- Day 822 (ECOG 1): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 37.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.543 mg/dL; Immunoglobulin G 28.4 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 4.93 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 54 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.2 mmol/L; Albumin 39 g/L; Total Protein 8.4 g/dL; Glucose 8.97 mmol/L.

Other clinical attributes
- Day -20: Weight: 95 kg; Height: 172 cm.

Biospecimens (2 samples)
- Sample MMRF_2310_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_2310_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
